Somatic mutation profile of tumor specimen TCGA-ZJ-AAXF-01A (aliquot TCGA-ZJ-AAXF-01A-31D-A42O-09) from TCGA case TCGA-ZJ-AAXF, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 62.2 years (22,709 days).
Specimen TCGA-ZJ-AAXF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7c2b416-4924-4cf6-9242-5f36505837eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZJ-AAXF-10A (Blood Derived Normal), aliquot TCGA-ZJ-AAXF-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59063574-0761-4f99-aafb-c47839729d61

The open-access MAF lists 54 somatic variants for this specimen: 44 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 38, Silent 10, Nonsense Mutation 3, Frame Shift Ins 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS9 | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99900028; called by muse, mutect2, varscan2
- AHNAK2 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1048400750, COSV100318622; called by muse, mutect2, varscan2
- BHMT | c.607G>C p.V203L | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.501); catalogued as COSV57154226, COSV99165482; called by muse, mutect2, varscan2
- CBY2 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.09); catalogued as rs761413589, COSV60117619; called by muse, mutect2, varscan2
- CHRNA1 | c.1408G>A p.V470M (on ENST00000261007 / NM_001039523.3; = p.V445M on NM_000079.4) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs372104868; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUX2 | c.2027C>T p.P676L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.059); catalogued as rs1003474809, COSV99920467; called by muse, mutect2, varscan2
- DSCAM | c.2936C>T p.A979V | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs369435140; called by muse, mutect2, varscan2
- ECEL1 | c.1921A>G p.S641G | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV100458913; called by muse, mutect2
- FAM160B2 | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 7/106 reads (7%) | catalogued as rs1315632165, COSV99249180; called by muse, mutect2
- FAM177A1 | c.270G>A p.P90= (on ENST00000382406 / NM_001289022.2; = p.P113= on NM_173607.5) | Splice Region (SNP) | VAF 43/156 reads (28%) | catalogued as rs1266182217, COSV99805891; called by muse, mutect2, varscan2
- GRB10 | c.1486G>A p.G496R (on ENST00000398812; = p.G450R on NM_001001549.3) | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1247618428; called by muse, mutect2
- HPS3 | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs747708121, COSV56055621; called by mutect2, varscan2
- HTATSF1 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54477365, COSV99511853; called by muse, mutect2, varscan2
- ICA1 | c.1376T>C p.F459S | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99655719; called by muse, mutect2, varscan2
- ING2 | c.400G>C p.A134P | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100180491; called by muse, mutect2, varscan2
- IRAG1 | c.128C>T p.T43I | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.037); catalogued as COSV101351565; called by muse, mutect2, varscan2
- KMT2D | c.9262G>T p.G3088W | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99985003; called by muse, mutect2, varscan2
- LAMC3 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as rs1162613016, COSV63088593; called by muse, mutect2, varscan2
- LEFTY2 | c.124G>A p.V42I | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as rs781615840, COSV100832643; called by muse, mutect2, varscan2
- LINS1 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV59078595, COSV59080068; called by muse, mutect2, varscan2
- LRFN5 | c.1938G>T p.K646N | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.017); catalogued as COSV53267110, COSV53276322; called by muse, mutect2, varscan2
- LRRIQ3 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV63040877; called by muse, mutect2, varscan2
- MAP2 | c.5396C>T p.S1799L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1243992461, COSV52304937; called by muse, mutect2, varscan2
- MON1B | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.435); catalogued as rs200585249, COSV99941825; called by muse, mutect2, varscan2
- OPRM1 | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs199560373, COSV100002191; called by muse, mutect2
- PCDH9 | c.3396G>T p.E1132D (on ENST00000377865 / NM_203487.3; = p.E1098D on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.643); catalogued as COSV100122734; called by muse, mutect2, varscan2
- PCDHA2 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); catalogued as rs1477834475, COSV65364457; called by muse, mutect2
- PLEC | c.11573G>A p.R3858H (on ENST00000322810 / NM_201380.4; = p.R3748H on NM_000445.5) | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs781986718, COSV100517783; called by muse, mutect2
- PRTG | c.342G>C p.L114F | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV101221464; called by muse, mutect2, varscan2
- RFX5 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV99303256; called by muse, mutect2, varscan2
- RGS22 | c.3110G>A p.R1037H | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs182707509, COSV100693664, COSV62667623; called by muse, mutect2, varscan2
- RGS8 | c.52G>A p.G18R (on ENST00000367556 / NM_001369564.2; = p.G36R on NM_033345.3) | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99276857; called by muse, mutect2
- SCN5A | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as rs794728853, COSV61115246; ClinVar: uncertain significance; called by muse, mutect2
- SEC14L5 | c.900_902del p.L301del | In Frame Del (DEL) | VAF 8/58 reads (14%) | catalogued as rs1177707773; called by pindel, varscan2
- SPTBN4 | c.6399C>A p.F2133L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV58958889; called by muse, mutect2, varscan2
- ST8SIA1 | c.773G>C p.S258T | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV99683458; called by muse, mutect2
- TAPBP | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs1364368348, COSV101444966; called by muse, mutect2, varscan2
- TEKT3 | c.184T>C p.S62P | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100107250; called by muse, varscan2
- TRAF3 | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 17/66 reads (26%) | catalogued as COSV61026797; called by muse, mutect2, varscan2
- ZC2HC1C | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 6/89 reads (7%) | catalogued as COSV99472966; called by muse, mutect2
- TNIP2 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.124); called by muse, mutect2
- TRIP12 | c.4298dup p.H1434Afs*2 | Frame Shift Ins (INS) | VAF 13/104 reads (13%) | called by mutect2, pindel, varscan2
- UBR7 | c.1273A>G p.S425G | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.746); called by muse, mutect2
- AKR1C3 | c.831C>A p.I277= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV101003155; called by muse, mutect2, varscan2
- ATP6AP1 | c.1272C>T p.P424= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs782713260, COSV63895809; called by muse, mutect2, varscan2
- C3orf84 | c.225C>T p.I75= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as rs749509141, COSV100234296; called by muse, mutect2
- DPP10 | c.1389C>T p.R463= | Silent (SNP) | VAF 20/107 reads (19%) | catalogued as COSV100065201, COSV100070480; called by muse, mutect2, varscan2
- DUSP11 | c.258C>T p.L86= | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as rs749572997, COSV99731200; called by muse, mutect2, varscan2
- EDNRB | c.279G>A p.P93= (on ENST00000377211 / NM_001201397.1; = p.P3= on NM_000115.5) | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs201820859, COSV57518982; called by muse, mutect2, varscan2
- FBXL20 | c.573G>C p.V191= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as COSV99234604; called by muse, varscan2
- IRS4 | c.3678G>A p.P1226= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as rs1223140636, COSV64532998; called by muse, mutect2, varscan2
- PRAMEF4 | c.213G>A p.L71= | Silent (SNP) | VAF 43/257 reads (17%) | catalogued as COSV99340115; called by muse, mutect2, varscan2
- TCTN2 | c.171A>C p.A57= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV100315348; called by muse, mutect2, varscan2
